CTSP case CTSP-AD14 — CTSP-DLBCL1: CTSP Diffuse Large B-Cell Lymphoma (DLBCL) CALGB 50303
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/9b42ae91-9921-48a0-8cac-e6b637804b3d

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1952; Vital status: Alive.

Diagnoses (1)
1. Diffuse large B-cell lymphoma, NOS: ICD-O-3 morphology code: 9680/3; Age at diagnosis: 56.9 years (20,786 days); Method of diagnosis: Biopsy; Ann Arbor pathologic stage: Stage III; Days to last follow up: 2,248 days (6.2 years); Best overall response: Partial Response; Ann Arbor extranodal involvement: No; Double expressor lymphoma: No; International Prognostic Index (IPI): Low-Intermediate Risk.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 82 kg; Height: 165 cm; BMI: 30.1.

Biospecimens (1 sample)
- Sample DLBCL11311-sample: Sample type: Tumor; Tissue type: Tumor.
